Somatic mutation profile of tumor specimen TARGET-10-PARMSB-09A (aliquot TARGET-10-PARMSB-09A-01D) from TARGET case TARGET-10-PARMSB, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.9 years (5,059 days).
Specimen TARGET-10-PARMSB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 405b7612-7616-4aa3-8177-d026dd7ed3c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARMSB-10A (Blood Derived Normal), aliquot TARGET-10-PARMSB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/104c8140-ac4f-4916-a4ec-6eba4c5dd09c

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Frame Shift Ins 2, Silent 2, In Frame Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP31 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51788638; called by muse, mutect2, varscan2
- DNAH17 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs776938478; called by muse, mutect2, varscan2
- FLT3 | c.1730_1731insCCTGGGGGG p.Q577delinsHLGG | In Frame Ins (INS) | VAF 9/34 reads (26%) | catalogued as COSV54046957; called by pindel, varscan2
- PLCH2 | c.1402G>A p.V468M | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs756323592, COSV99616837; called by muse, mutect2, varscan2
- SYN1 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs374210167; called by muse, mutect2, varscan2
- ARRDC3 | c.208_209insGGCGGGAG p.A70Gfs*13 | Frame Shift Ins (INS) | VAF 48/124 reads (39%) | called by mutect2, varscan2
- ARRDC3 | c.207delinsCGGGCGGGA p.A70Gfs*13 | Frame Shift Ins (INS) | VAF 61/144 reads (42%) | called by mutect2*, pindel, varscan2*
- ERAP2 | c.2167A>G p.K723E | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- SOX6 | c.1632G>A p.T544= (on ENST00000528429 / NM_001145819.2; = p.T517= on NM_017508.3) | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as rs201059426, COSV57050887; called by muse, mutect2, varscan2
- TACC2 | c.7182C>T p.S2394= (on ENST00000334433; = p.S472= on NM_006997.4) | Silent (SNP) | VAF 43/107 reads (40%) | catalogued as rs928356195; called by muse, mutect2, varscan2
- IGHV2-70 | chr14:106770576 ins GCCCGACCCCC | 3'Flank (INS) | VAF 8/27 reads (30%) | called by mutect2, pindel, varscan2
